TCGA case TCGA-HT-A619 — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Case Western - St Joes. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c13bac88-c85b-4ee3-a51c-fd503cd7e726

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 51 years; Vital status: Alive.

Diagnoses (2)
1. Oligodendroglioma, anaplastic (the primary disease): ICD-O-3 morphology code: 9451/3; ICD-10 code: C71.0; Tissue or organ of origin: Cerebrum; Site of resection or biopsy: Nervous system, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 51.6 years (18,857 days); Year of diagnosis: 2012; Tumor grade: G3; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: Yes; Days to last follow up: 651 days (1.8 years); First symptom longest duration: 0-30 Days; First symptom prior to diagnosis: Motor or Movement Changes; Sites of involvement: Brain, Frontal lobe.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Days to treatment start: 19 days; Days to treatment end: 443 days (1.2 years); Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation Therapy, NOS; Timepoint category: Prior to Diagnosis; Treatment anatomic sites: Head, Face or Neck, NOS.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Oligodendroglioma, NOS: ICD-O-3 morphology code: 9450/3; Tissue or organ of origin: Brain, NOS; Laterality: Left; Classification of tumor: Prior primary; Age at diagnosis: 41.2 years (15,039 days); Days to diagnosis: -3,818 days (-10.5 years).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -3,818 days (-10.5 years); Treatment anatomic sites: Brain.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: -3,787 days (-10.4 years); Treatment anatomic sites: Locoregional Site.
   Recorded as not given: Pharmaceutical Therapy, NOS.

Follow-up (4 entries)
- Days to follow up: 434 days (1.2 years); Disease response: Tumor Free.
- Days to follow up: 587 days (1.6 years); Disease response: Tumor Free.
- Days to follow up: 651 days (1.8 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: preoperative.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Motor / Movement Change.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-HT-A619-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 130 mg.
  Slide TCGA-HT-A619-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-HT-A619-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-HT-A619-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Oligodendroglioma; History neoadjuvant treatment: Yes, Radiation Prior to Resection; Prospective collection: No; Retrospective collection: Yes; History ionizing radiation to head: Yes; Tumor status: Tumor free; Tumor site: Supratentorial, Frontal Lobe; Supratentorial localization: Not listed in Medical Record; History seizures: No; History headaches: No; Symp changes mental status: No; Symp changes visual: No; Symp changes sensory: No; Symp changes motor movement: Yes; Related symptom first present: Motor/Movement Changes; First symptom longest duration: 0 - 30 Days; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Drug treatment: Pharmaceutical therapy drug name: Temodar.
- Follow-up form 1: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy histological type: oligodendroglioma.
- Other malignancy form, Surgery: Other malignancy surgery type: craniotomy partial resection.
- Other malignancy form, Radiation treatment: Radiation therapy extent: Locoregional; History radiation treatment to site of TCGA tumor: Yes.

GDC annotations on this case (curator notes; quoted as recorded):
- History of unacceptable prior treatment related to a prior/other malignancy: Patient had a prior LGG diagnosis, surgery and radiation to the head. TCGA tumor was resected 10 years later.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 651 days; disease-specific survival: no event (censored), 651 days; disease-free interval: no event (censored), 651 days; progression-free interval: no event (censored), 651 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-HT-A619-01): tumor purity 0.9, ploidy 3.67, whole-genome doublings 1 (call status: maf_call).
